CCDI case PBCFHV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/0e1f784c-dac9-4c8a-88a6-05291c9f9d3a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 15.4 years (5,612 days).

Biospecimens (3 samples)
- Samples 0DQQBW, 0DQQCE (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQQCT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
